Gene-level copy-number profile of tumor specimen TCGA-EK-A2PG-01A from TCGA case TCGA-EK-A2PG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 89.0 years (32,500 days).
Specimen TCGA-EK-A2PG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.6347a231-5d7d-4499-8366-d5e172026154.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2PG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2522bf2c-aa4b-4014-b4cb-d165bb30edaf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 730; copy number 2: 5,679; copy number 3: 23,230; copy number 4: 17,655; copy number 5: 4,475; copy number 6: 5,820; copy number 7: 97; copy number 8: 580; copy number 9: 1,536; copy number 12: 1; copy number 14: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2PG-01A-11D-A18H-01): tumor purity 0.79, ploidy 3.72, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:79,072,132–79,249,023, 3 genes: AC026888.1, AC022469.1, AC022469.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,221 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,198,086–52,250,599, 7 genes, copy number 14 (within-gene range 3–14): ALAS1, AC097637.2, TLR9, AC097637.1, TWF2, AC006252.1, PPM1M.
- chr7:40,135,005–40,860,763, 1 gene, copy number 8 (within-gene range 6–8): SUGCT.
- chr7:40,538,127–71,713,600, 579 genes, copy number 8 (broad region; genes not listed).
- chr8:43,672,823–145,066,685, 1,536 genes, copy number 9 (broad region; genes not listed).
- chr9:3,824,127–4,348,392, 1 gene, copy number 7 (within-gene range 6–7): GLIS3.
- chr9:4,070,906–6,197,248, 55 genes, copy number 7: AL359095.1, AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1.
- chr10:1,361,001–1,361,637, 1 gene, copy number 12: AL513304.1.
- chr15:43,197,227–44,195,271, 41 genes, copy number 7 (within-gene range 4–7): EPB42, TGM5, Y_RNA, ATP5PDP1, TGM7, AC009852.1, LCMT2, ADAL, ZSCAN29, TUBGCP4, RN7SL487P, TP53BP1, MAP1A, PPIP5K1, CKMT1B, STRC, RNU6-554P, AC011330.3, CATSPER2, RNU6-610P, AC011330.2, PDIA3P2, AC011330.1, CKMT1A, STRCP1, RNU6-353P, CATSPER2P1, RNU6-354P, PDIA3, ELL3, AC018512.1, SERF2, MIR1282, SERINC4, HYPK, MFAP1, WDR76, Y_RNA, FRMD5, PIN4P1, ACTBP7.

Autosomal genes at a single copy (total copy number 1): 730. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
